Surgical pathology report (de-identified scan), TCGA case TCGA-26-6174, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-6174-01A (Primary Tumor).

[page 1 of 2]
TCGA-26-6174

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Right parietal tumor () A. Frozen Section Charge
() B. Right parietal tumor () C. Posterior brain
lesion () C. Frozen Section Charge ()

CLINICAL HISTORY: Right parietal lobe lesion.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Right parietal tumor
- B. Right parietal tumor
- C. Posterior brain lesion

A. The specimen is received fresh for frozen section, designated "Right parietal tumor" and consists of three fragments of tan-white tissue that range from 0.1 to 0.3 cm in greatest dimension. Representative section is submitted for frozen section evaluation, FSA1. Frozen section diagnosis is "Infiltrating glioma. Grade defer to permanent," per Dr.

The residual frozen section tissue is submitted in cassette FSA1 and the remaining tissue is submitted in cassette A2.

B. The specimen is received fresh, designated "Right parietal tumor" and consists of a 1.4 x 1.3 x 0.6 cm aggregate of gray-tan to tan-white tissue. The specimen is submitted in toto in cassettes B1 through B3.

C. The specimen is received fresh for frozen section, designated "Posterior brain lesion" and consists of a 1.5 x 0.9 x 0.5 cm aggregate of gray-tan to tan-white tissue. A representative piece is submitted for frozen section evaluation FSC1. Frozen section diagnosis is "High grade glioma," per . The residual frozen section tissue is submitted in cassette FSC1 and the remaining tissue is submitted entirely in cassettes C2 and C3.

DIAGNOSIS:

- A. "Right parietal tumor, craniotomy and resection":
Glioblastoma multiforme (WHO Grade IV) (see comment)
- B. "Right parietal tumor, craniotomy and resection":
Glioblastoma multiforme (WHO Grade IV) (see comment)

[page 2 of 2]
[REDACTED]

C. "Posterior brain lesion, craniotomy and resection":
Glioblastoma multiforme (WHO Grade IV) (see comment)

COMMENT: Sections show a high grade infiltrating astrocytoma with prominent nuclear pleomorphism, increased mitoses, vascular endothelial proliferation and necrosis including focal pseudopalisading necrosis. These features support the diagnosis and are best represented in slides B1 and C2.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosecutor/Pathologist: [REDACTED]

ICD9 Codes: 191.9

[REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Pathologist

Electronically signed [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4eb204f0-60d6-4a18-8b0b-10f3f3f3bf4b (TCGA-26-6174.B5EF9CB5-A4C5-4D0E-9A94-279BBF646905.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).